Somatic mutation profile of tumor specimen C3L-02513-03 (aliquot CPT0210240006) from CPTAC case C3L-02513, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G1; Age at diagnosis: 74.0 years (27,012 days).
Specimen C3L-02513-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6091e33b-202a-4f0d-9e95-cb1d44fac085.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02513-31 (Blood Derived Normal), aliquot CPT0217640002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86af7cf9-1a82-47af-9e52-e1c2217ad081

The open-access MAF lists 66 somatic variants for this specimen: 38 protein-altering or splice-affecting, 18 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 18, 5'UTR 4, Intron 4, Nonsense Mutation 2, Frame Shift Del 2, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 71/298 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAR | c.2941A>G p.M981V | Missense Mutation (SNP) | VAF 72/513 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1284803985; called by muse, mutect2, varscan2
- AVPR2 | c.494C>G p.A165G | Missense Mutation (SNP) | VAF 49/268 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as rs1557100698, CM025909; called by muse, mutect2, varscan2
- CEP162 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.103); catalogued as rs768512946; called by muse, mutect2
- EDA2R | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as rs773332895, COSV53631955; called by muse, mutect2
- GATA5 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 52/253 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781802523, COSV53346089; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GEN1 | c.1217G>T p.R406L | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1183092755, COSV100437752, COSV58056387; called by muse, mutect2, varscan2
- HYLS1 | c.732G>C p.Q244H | Missense Mutation (SNP) | VAF 13/354 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV54993018; called by muse, mutect2
- IRF2BP2 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 187/351 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as rs1446016956; called by muse, mutect2, varscan2
- ITIH5 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 48/666 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.894); catalogued as rs747885557; called by muse, mutect2
- MED14 | c.1201C>A p.L401M | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61358276; called by muse, mutect2, varscan2
- NUP205 | c.5714G>C p.W1905S | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53660787; called by muse, mutect2, varscan2
- OR2D3 | c.8C>G p.S3C | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.241); catalogued as COSV100505114; called by muse, mutect2, varscan2
- OR7A17 | c.812G>A p.S271N | Missense Mutation (SNP) | VAF 48/302 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.365); catalogued as rs1234435023; called by muse, mutect2, varscan2
- TPTE | c.119G>T p.S40I | Missense Mutation (SNP) | VAF 52/374 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as rs1223320545; called by muse, mutect2, varscan2
- AMH | c.1342C>T p.R448W | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.599); called by muse, mutect2
- ANGPTL6 | c.727C>A p.P243T | Missense Mutation (SNP) | VAF 76/288 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- ANK2 | c.7645G>A p.E2549K | Missense Mutation (SNP) | VAF 17/335 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CCT5 | c.144G>C p.M48I | Missense Mutation (SNP) | VAF 44/630 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- CNNM2 | c.268G>C p.G90R | Missense Mutation (SNP) | VAF 9/229 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- FOXR1 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 101/474 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- GRM5 | c.1247T>A p.M416K | Missense Mutation (SNP) | VAF 123/478 reads (26%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- HOXA9 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 67/252 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGB4 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 74/530 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- KIF5B | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- MRO | c.423A>T p.L141F | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.991); called by muse, mutect2
- MUC16 | c.4046C>A p.T1349N | Missense Mutation (SNP) | VAF 35/360 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- OR4N5 | c.739A>T p.I247L | Missense Mutation (SNP) | VAF 86/327 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- OR56A5 | c.709A>G p.M237V | Missense Mutation (SNP) | VAF 81/313 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OSBPL6 | c.450A>G p.I150M | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PPARG | c.499_502del p.I167Dfs*2 (on ENST00000287820 / NM_015869.5; = p.I137Dfs*2 on NM_005037.7) | Frame Shift Del (DEL) | VAF 48/244 reads (20%) | called by mutect2, pindel, varscan2
- RBM10 | c.1831del p.E611Rfs*93 | Frame Shift Del (DEL) | VAF 100/258 reads (39%) | called by mutect2, pindel, varscan2
- SERPINF2 | c.691C>T p.L231F | Missense Mutation (SNP) | VAF 13/418 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLBP | c.17G>T p.R6L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SLC12A5 | c.1859C>T p.T620I (on ENST00000454036 / NM_001134771.2; = p.T597I on NM_020708.5) | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.403); called by muse, varscan2
- SLC33A1 | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 8/230 reads (3%) | called by muse, mutect2
- SLC4A2 | c.2287T>G p.L763V | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SYDE2 | c.973C>T p.Q325* | Nonsense Mutation (SNP) | VAF 11/268 reads (4%) | called by muse, mutect2
- ABCA3 | c.957C>T p.A319= | Silent (SNP) | VAF 133/502 reads (26%) | catalogued as rs368050715; called by muse, mutect2, varscan2
- ATG101 | c.414G>A p.Q138= | Silent (SNP) | VAF 12/388 reads (3%) | called by muse, mutect2
- CAMP | c.315C>T p.D105= (on ENST00000296435; = p.D102= on NM_004345.5) | Silent (SNP) | VAF 26/210 reads (12%) | catalogued as rs201842351, COSV56482414; called by muse, mutect2, varscan2
- CAMSAP1 | c.3969T>G p.A1323= | Silent (SNP) | VAF 66/210 reads (31%) | called by muse, mutect2, varscan2
- CCDC134 | c.204C>T p.V68= | Silent (SNP) | VAF 49/177 reads (28%) | called by muse, mutect2, varscan2
- CNTN5 | c.939T>C p.A313= | Silent (SNP) | VAF 55/187 reads (29%) | catalogued as rs746678590, COSV99675624; called by muse, mutect2, varscan2
- DPPA4 | c.361C>T p.L121= | Silent (SNP) | VAF 26/144 reads (18%) | called by muse, mutect2, varscan2
- LRFN1 | c.987G>T p.P329= | Silent (SNP) | VAF 101/457 reads (22%) | catalogued as rs1245965300; called by muse, mutect2, varscan2
- MED13 | c.759A>G p.K253= | Silent (SNP) | VAF 34/164 reads (21%) | catalogued as rs1433736896; called by muse, mutect2, varscan2
- MYT1 | c.2341C>T p.L781= | Silent (SNP) | VAF 49/168 reads (29%) | called by muse, mutect2, varscan2
- NT5DC2 | c.12G>A p.E4= | Silent (SNP) | VAF 38/143 reads (27%) | catalogued as rs148067255; called by muse, mutect2, varscan2
- PHIP | c.855T>C p.Y285= | Silent (SNP) | VAF 48/221 reads (22%) | catalogued as rs774075356; called by muse, mutect2, varscan2
- PLCD3 | c.462G>T p.A154= | Silent (SNP) | VAF 92/286 reads (32%) | called by muse, mutect2, varscan2
- SARM1 | c.990C>T p.L330= | Silent (SNP) | VAF 44/146 reads (30%) | called by muse, mutect2, varscan2
- SH3TC1 | c.2718G>A p.L906= | Silent (SNP) | VAF 32/170 reads (19%) | called by muse, mutect2, varscan2
- TMEM132D | c.1002C>A p.G334= | Silent (SNP) | VAF 29/119 reads (24%) | catalogued as COSV70603216; called by muse, mutect2, varscan2
- ZFY | c.1761G>A p.L587= | Silent (SNP) | VAF 11/345 reads (3%) | called by muse, mutect2
- ZNF560 | c.1128T>C p.Y376= | Silent (SNP) | VAF 48/211 reads (23%) | called by muse, mutect2, varscan2
- AC020907.6 | c.-552G>A | 5'UTR (SNP) | VAF 12/328 reads (4%) | called by muse, mutect2
- AP4M1 | c.-12T>G | 5'UTR (SNP) | VAF 89/436 reads (20%) | called by muse, mutect2, varscan2
- EML2 | chr19:45642227 G>A | 5'Flank (SNP) | VAF 12/234 reads (5%) | catalogued as COSV55601480; called by muse, mutect2
- LINC02756 | n.311+7311T>C | Intron (SNP) | VAF 41/199 reads (21%) | called by muse, mutect2, varscan2
- RPL12 | c.38-11T>G | Intron (SNP) | VAF 40/186 reads (22%) | called by muse, mutect2
- SMARCAD1 | c.-2A>G | 5'UTR (SNP) | VAF 42/336 reads (13%) | called by muse, mutect2, varscan2
- SNORD3B-1 | n.229G>A | RNA (SNP) | VAF 46/642 reads (7%) | catalogued as rs374267719; called by muse, mutect2
- SORBS1 | c.2128+850G>T | Intron (SNP) | VAF 56/251 reads (22%) | catalogued as COSV53362309; called by muse, mutect2, varscan2
- TAFA5 | c.112+56837G>A | Intron (SNP) | VAF 26/204 reads (13%) | catalogued as rs752523222; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 24/271 reads (9%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2
